TCGA case TCGA-EB-A85I — Skin Cutaneous Melanoma (TCGA-SKCM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Nevi and Melanomas; Primary site: Skin; Tissue source site: Asterand. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/50dc9c63-c491-4afc-ab12-74b40eba58b6

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Ukraine; Age at index: 66 years; Vital status: Alive.

Diagnoses (2)
1. Malignant melanoma, NOS (the primary disease): ICD-O-3 morphology code: 8720/3; ICD-10 code: C44.7; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Skin of lower limb and hip; Classification of tumor: primary; Age at diagnosis: 66.8 years (24,408 days); Year of diagnosis: 2013; AJCC staging edition: 7th; AJCC pathologic T: T4b; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIC; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 362 days; Melanoma known primary: Yes.
   Pathology details: Consistent pathology review: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, prior to procurement; adjuvant Pharmaceutical Therapy, NOS; Radiation Therapy, NOS, prior to procurement.
2. Malignant melanoma, NOS: Tissue or organ of origin: Skin, NOS; Classification of tumor: primary; Sites of involvement: Skin, Trunk; Ulceration indicator: Yes.
   Pathology details: Breslow thickness category: >4.0 mm.
   Recorded as not given: Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: -5 days; Disease response: Tumor Free.
- Days to follow up: 362 days; Disease response: Tumor Free.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 82 kg; Height: 170 cm; BMI: 28.4.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-EB-A85I-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT; Initial weight: 370 mg.
  Slide TCGA-EB-A85I-01A-01-TSA: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-EB-A85I-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-EB-A85I-10B: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: Tumor free; Breslow thickness at diagnosis: 10; Radiation therapy to primary: No; Primary melanoma skin type: Non-glabrous skin; Prior radiation therapy: No; History neoadjuvant treatment: No; New tumor event diagnosis indicator: No.
- Sites of primary melanomas: Primary at diagnosis count: 1.
- Sites of primary melanomas, Site: Submitted tumor site: Trunk; Melanoma primary count: 1.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; Subsequent known primaries: No; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 362 days; disease-specific survival: no event (censored), 362 days; progression-free interval: no event (censored), 362 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-EB-A85I-01A-11D-A34T-01): tumor purity 0.52, ploidy 1.94, whole-genome doublings 0.
